Somatic mutation profile of tumor specimen TCGA-BC-A10U-01A (aliquot TCGA-BC-A10U-01A-11D-A12Z-10) from TCGA case TCGA-BC-A10U, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G2; Age at diagnosis: 69.3 years (25,305 days).
Specimen TCGA-BC-A10U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c9a7442-4441-4f25-bb08-9cfa45b723af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BC-A10U-11A (Solid Tissue Normal), aliquot TCGA-BC-A10U-11A-11D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e57f2104-6ff8-4eb4-9fce-7a3bcdf63108

The open-access MAF lists 146 somatic variants for this specimen: 120 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 24, Nonsense Mutation 10, Frame Shift Del 7, Frame Shift Ins 4, Splice Site 3, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 53/82 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: drug response / pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTRT1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 203/306 reads (66%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); catalogued as COSV64418899, COSV64419648; called by muse, mutect2, varscan2
- ADAM11 | c.2130T>A p.S710R | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV52344039; called by muse, mutect2, varscan2
- ADAMTS8 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs1026709260, COSV57290853; called by muse, mutect2, varscan2
- ALDH18A1 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64661994; called by muse, mutect2, varscan2
- ALMS1 | c.8855G>C p.G2952A | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV52501456; called by muse, mutect2, varscan2
- ATAD5 | c.1219T>C p.F407L | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58971649; called by muse, mutect2, varscan2
- C10orf90 | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.041); catalogued as COSV52948727; called by muse, mutect2, varscan2
- C6orf118 | c.519G>T p.R173S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); catalogued as COSV57812104; called by muse, mutect2, varscan2
- C7orf61 | c.571dup p.R191Pfs*24 | Frame Shift Ins (INS) | VAF 15/72 reads (21%) | catalogued as rs767078637; called by mutect2, pindel, varscan2
- CADPS | c.884G>C p.C295S | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.214); catalogued as COSV51865580; called by muse, mutect2, varscan2
- CCDC14 | c.1740A>G p.I580M (on ENST00000488653; = p.I532M on NM_022757.5) | Missense Mutation (SNP) | VAF 119/317 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV59942782; called by muse, mutect2, varscan2
- CCDC65 | c.849C>A p.S283R | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.827); catalogued as COSV56739052; called by muse, mutect2, varscan2
- CFAP47 | c.5171T>C p.M1724T | Missense Mutation (SNP) | VAF 20/476 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV57970905; called by muse, mutect2
- CFAP54 | c.5215G>T p.D1739Y | Missense Mutation (SNP) | VAF 80/169 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100733160, COSV61574539; called by muse, mutect2, varscan2
- CHAT | c.420G>C p.Q140H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as COSV60319427; called by muse, mutect2, varscan2
- CHD4 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.366); catalogued as COSV58893745; called by muse, mutect2, varscan2
- COPA | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 159/263 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV54097285, COSV54102318; called by muse, mutect2, varscan2
- CST11 | c.401G>C p.S134T (on ENST00000377009 / NM_130794.2; = p.S99T on NM_080830.3) | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV65440421, COSV65440703; called by muse, mutect2, varscan2
- DCAF6 | c.1882G>C p.E628Q (on ENST00000312263 / NM_001349778.1; = p.E648Q on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 204/347 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.216); catalogued as COSV56574208; called by muse, mutect2, varscan2
- DNAH8 | c.4056G>A p.M1352I | Missense Mutation (SNP) | VAF 65/303 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV59421789; called by muse, mutect2, varscan2
- DRP2 | c.2441C>G p.A814G | Missense Mutation (SNP) | VAF 109/175 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67870513; called by muse, mutect2, varscan2
- EIF3E | c.817G>T p.V273F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.359); catalogued as COSV55201158; called by muse, mutect2, varscan2
- EIF4E1B | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.074); catalogued as COSV53779080; called by muse, mutect2, varscan2
- F2 | c.866A>G p.N289S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.186); catalogued as COSV61314592; called by muse, mutect2, varscan2
- FANK1 | c.395G>C p.G132A | Missense Mutation (SNP) | VAF 202/494 reads (41%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.622); catalogued as COSV64156039; called by muse, mutect2, varscan2
- FAT3 | c.12727A>G p.S4243G | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV53071126; called by muse, mutect2, varscan2
- GAL3ST3 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV61748583; called by muse, mutect2, varscan2
- GNB5 | c.1007G>T p.S336I (on ENST00000261837 / NM_016194.4; = p.S294I on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55897647; called by muse, mutect2, varscan2
- GPRIN2 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1555019445, COSV65400101; called by muse, mutect2, varscan2
- H4C7 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 106/198 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs140916075; called by muse, mutect2, varscan2
- HIVEP1 | c.6924G>T p.E2308D | Missense Mutation (SNP) | VAF 79/320 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0.024); catalogued as COSV65098332; called by muse, mutect2, varscan2
- IGFBP4 | c.285C>A p.H95Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.862); catalogued as rs777867036, COSV54096531; called by muse, mutect2, varscan2
- IRAK3 | c.1424C>A p.P475Q | Missense Mutation (SNP) | VAF 89/254 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.352); catalogued as COSV54159070; called by muse, mutect2, varscan2
- IRF2 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1255904730, COSV66928316; called by muse, mutect2, varscan2
- KCMF1 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 97/244 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs777236299, COSV69053080; called by muse, mutect2, varscan2
- KMT2C | c.4867G>T p.E1623* | Nonsense Mutation (SNP) | VAF 105/197 reads (53%) | catalogued as COSV51274799; called by muse, mutect2, varscan2
- KNDC1 | c.329C>A p.P110H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58830295; called by muse, mutect2, varscan2
- LAMC1 | c.2579A>G p.Y860C | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs769260014, COSV51132056; called by muse, mutect2, varscan2
- LMNB1 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 34/94 reads (36%) | catalogued as COSV54396384; called by muse, mutect2, varscan2
- MACC1 | c.574T>A p.C192S | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60540530; called by muse, mutect2, varscan2
- MACROD1 | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV55356296; called by muse, mutect2, varscan2
- MACROH2A1 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as rs769661746, COSV56893003; called by muse, mutect2, varscan2
- MAGEB6 | c.1034G>C p.R345P | Missense Mutation (SNP) | VAF 115/161 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV100983729; called by muse, mutect2, varscan2
- MAPK7 | c.1825C>T p.P609S | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV55189123; called by muse, mutect2, varscan2
- MFSD5 | c.890C>A p.S297Y | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV61565071; called by muse, mutect2, varscan2
- MINDY3 | c.882+2T>C p.X294_splice | Splice Site (SNP) | VAF 50/149 reads (34%) | catalogued as COSV53217719; called by muse, mutect2, varscan2
- MUC16 | c.30244G>T p.E10082* | Nonsense Mutation (SNP) | VAF 61/181 reads (34%) | catalogued as COSV67441319; called by muse, mutect2, varscan2
- MUC5B | c.16662C>A p.D5554E | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0.07); catalogued as COSV71589691; called by muse, mutect2, varscan2
- MYBL2 | c.1333C>G p.P445A | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV53827294; called by muse, mutect2, varscan2
- MYT1L | c.3395A>G p.N1132S | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV67701049; called by muse, mutect2, varscan2
- NAALAD2 | c.2155A>G p.K719E | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.689); catalogued as COSV58958318; called by muse, mutect2, varscan2
- NCAPD3 | c.1292T>C p.L431P | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV73257796; called by muse, mutect2, varscan2
- NEDD4L | c.796G>C p.G266R | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV56839405; called by muse, mutect2, varscan2
- NEK11 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.115); catalogued as COSV53907373; called by muse, mutect2, varscan2
- NID2 | c.1588C>A p.H530N | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV53492425; called by muse, mutect2, varscan2
- NPAS4 | c.1091C>T p.T364I | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV60648656; called by muse, mutect2, varscan2
- OBSCN | c.17959C>T p.R5987W | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs757952523, COSV52735675; called by muse, varscan2
- OR10G7 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 221/455 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV57865510; called by muse, mutect2, varscan2
- OR2J3 | c.766A>T p.I256F | Missense Mutation (SNP) | VAF 183/786 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV65848604; called by muse, mutect2, varscan2
- OR2L13 | c.317T>C p.M106T | Missense Mutation (SNP) | VAF 154/279 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV63547454; called by muse, mutect2, varscan2
- OR2T27 | c.870C>A p.Y290* | Nonsense Mutation (SNP) | VAF 72/511 reads (14%) | catalogued as COSV61280515; called by muse, mutect2, varscan2
- OR51L1 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 154/339 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58623748; called by muse, varscan2
- OR52E2 | c.953A>T p.E318V | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV58611710; called by muse, mutect2
- OSBPL5 | c.2446C>T p.Q816* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99720374; called by muse, mutect2, varscan2
- PARP11 | c.35C>G p.A12G | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.023); catalogued as COSV57392878; called by muse, mutect2, varscan2
- PCDH10 | c.425C>A p.P142H | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV52086706; called by muse, mutect2, varscan2
- PCYOX1L | c.632C>G p.A211G | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as COSV51002047; called by muse, mutect2, varscan2
- PLEKHG4B | c.223C>T p.R75W (on ENST00000283426; = p.R431W on NM_052909.5) | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs369792305; called by muse, mutect2, varscan2
- PLEKHG7 | c.1395C>G p.Y465* | Nonsense Mutation (SNP) | VAF 36/102 reads (35%) | catalogued as COSV60820947; called by muse, mutect2, varscan2
- PRADC1 | c.278G>C p.G93A | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57819594; called by muse, mutect2, varscan2
- PRKG1 | c.177G>T p.Q59H | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.224); catalogued as COSV64820861; called by muse, mutect2, varscan2
- PRPF4B | c.2465T>C p.L822P | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61783154; called by muse, mutect2, varscan2
- PRSS16 | c.530G>T p.S177I | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV57914639; called by muse, mutect2, varscan2
- RFC1 | c.1060C>G p.P354A | Missense Mutation (SNP) | VAF 102/253 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV62898243; called by muse, mutect2, varscan2
- SACS | c.12988A>G p.R4330G | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66533231; called by muse, mutect2
- SH3YL1 | c.980T>G p.L327R | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV62155331, COSV62157668; called by muse, mutect2, varscan2
- SHKBP1 | c.980T>A p.I327N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV52537354; called by muse, mutect2, varscan2
- SLC22A8 | c.1283G>A p.C428Y | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60323319; called by muse, mutect2, varscan2
- SNX13 | c.808G>C p.D270H | Missense Mutation (SNP) | VAF 103/326 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68063575; called by muse, mutect2, varscan2
- SOHLH2 | c.187T>C p.C63R | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV58520551; called by muse, mutect2, varscan2
- SORCS3 | c.2632G>C p.G878R | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV63793116; called by muse, mutect2, varscan2
- SRCAP | c.2140A>T p.K714* | Nonsense Mutation (SNP) | VAF 44/117 reads (38%) | catalogued as COSV52666882; called by muse, mutect2, varscan2
- SRCAP | c.2141A>G p.K714R | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.426); catalogued as COSV52666896; called by muse, mutect2, varscan2
- SSTR4 | c.1022A>G p.E341G | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.723); catalogued as COSV54796718; called by muse, mutect2
- STK39 | c.616G>T p.V206L | Missense Mutation (SNP) | VAF 119/331 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV63594014; called by muse, mutect2, varscan2
- STON2 | c.369G>C p.E123D | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.045); catalogued as COSV50842197; called by muse, mutect2, varscan2
- STXBP1 | c.1511C>T p.T504I | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT tolerated (0.14); PolyPhen benign (0.144); catalogued as COSV64811934; called by muse, mutect2, varscan2
- TBC1D26 | c.461A>G p.Q154R | Missense Mutation (SNP) | VAF 102/181 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV68608370; called by muse, varscan2
- TG | c.4362G>C p.Q1454H | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.359); catalogued as COSV55063773; called by muse, mutect2, varscan2
- TMEM131 | c.5646G>C p.E1882D | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as COSV51769300; called by muse, mutect2, varscan2
- TMPO | c.783+1G>C p.X261_splice | Splice Site (SNP) | VAF 49/134 reads (37%) | catalogued as COSV58460107; called by muse, mutect2, varscan2
- TNFRSF21 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 158/383 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV57279826; called by muse, mutect2, varscan2
- TNIP3 | c.22A>G p.T8A | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV50245644; called by muse, mutect2, varscan2
- TNXB | c.7247G>A p.G2416E (on ENST00000647633; = p.G2169E on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as rs912459761, COSV100926609, COSV64472491; called by muse, mutect2, varscan2
- TRRAP | c.1223A>G p.D408G | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs782557691, COSV62837970; called by muse, mutect2, varscan2
- UBR4 | c.1938+2T>C p.X646_splice | Splice Site (SNP) | VAF 40/92 reads (43%) | catalogued as COSV64382121; called by muse, mutect2, varscan2
- USP47 | c.3019G>T p.D1007Y (on ENST00000399455 / NM_001372095.1; = p.D919Y on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV60460453; called by muse, mutect2, varscan2
- VPS33A | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV57355819; called by muse, mutect2, varscan2
- WDR49 | c.1312G>A p.G438R (on ENST00000308378 / NM_001366158.1; = p.G779R on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/255 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57701356; called by muse, mutect2, varscan2
- ZCCHC2 | c.2569T>G p.F857V | Missense Mutation (SNP) | VAF 77/241 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV54035860; called by muse, mutect2, varscan2
- ZCCHC4 | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 125/324 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as rs755637965, COSV57179990, COSV57181006; called by muse, mutect2, varscan2
- ZGRF1 | c.3126G>C p.E1042D | Missense Mutation (SNP) | VAF 100/141 reads (71%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV58407251; called by muse, mutect2, varscan2
- ZNF2 | c.1093G>T p.D365Y (on ENST00000611147 / NM_001291605.2; = p.D352Y on NM_021088.4) | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.41); catalogued as COSV54635934; called by muse, mutect2, varscan2
- ZNF208 | c.1700C>A p.T567N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs1326463141, COSV68099617; called by muse, mutect2, varscan2
- ZNF28 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 14/398 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV100354489; called by muse, mutect2
- ZNF608 | c.3229T>A p.S1077T | Missense Mutation (SNP) | VAF 98/263 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as COSV60434875; called by muse, mutect2, varscan2
- ZNF700 | c.667A>T p.K223* | Nonsense Mutation (SNP) | VAF 71/178 reads (40%) | catalogued as COSV54310551; called by muse, mutect2, varscan2
- ABHD10 | c.629_632del p.S210* | Frame Shift Del (DEL) | VAF 78/201 reads (39%) | called by mutect2, pindel, varscan2
- ANK1 | c.1482del p.N495Tfs*38 | Frame Shift Del (DEL) | VAF 60/137 reads (44%) | called by mutect2, pindel, varscan2
- FRG2C | c.288C>A p.C96* | Nonsense Mutation (SNP) | VAF 410/2136 reads (19%) | called by muse, mutect2, varscan2
- ITIH2 | c.1538del p.V513Afs*29 | Frame Shift Del (DEL) | VAF 32/81 reads (40%) | called by mutect2, pindel, varscan2
- KMT2D | c.8_15del p.S3Tfs*4 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | called by mutect2, pindel, varscan2
- NUDT14 | c.295dup p.V99Gfs*4 | Frame Shift Ins (INS) | VAF 14/38 reads (37%) | called by mutect2, pindel, varscan2
- OR1J2 | c.376A>T p.I126L | Missense Mutation (SNP) | VAF 14/407 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.373); called by muse, mutect2
- PIEZO2 | c.6586_6595del p.A2196Wfs*37 | Frame Shift Del (DEL) | VAF 31/94 reads (33%) | called by mutect2, pindel, varscan2
- SFPQ | c.1532dup p.N511Kfs*12 | Frame Shift Ins (INS) | VAF 220/582 reads (38%) | called by mutect2, varscan2
- SYT12 | c.354_356delinsTC p.E119Rfs*19 | Frame Shift Del (DEL) | VAF 30/73 reads (41%) | called by pindel, varscan2*
- ZFX | c.1132_1181del p.A378* | Frame Shift Del (DEL) | VAF 106/132 reads (80%) | called by mutect2, pindel
- ZNF536 | c.1788_1791dup p.L598* | Frame Shift Ins (INS) | VAF 12/56 reads (21%) | called by mutect2, varscan2
- ATF7IP2 | c.1629A>G p.A543= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV61092021; called by muse, mutect2, varscan2
- BMI1 | c.618A>G p.L206= | Silent (SNP) | VAF 55/162 reads (34%) | catalogued as rs1162912651, COSV64958629; called by muse, mutect2, varscan2
- C2CD5 | c.2808G>C p.G936= | Silent (SNP) | VAF 78/214 reads (36%) | catalogued as COSV61722428; called by muse, mutect2, varscan2
- COL19A1 | c.1596C>T p.S532= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV59564271; called by muse, mutect2, varscan2
- COPS6 | c.99C>T p.C33= | Silent (SNP) | VAF 49/144 reads (34%) | catalogued as rs756804877, COSV57993645; called by muse, mutect2, varscan2
- ERO1B | c.270T>C p.C90= | Silent (SNP) | VAF 76/329 reads (23%) | catalogued as COSV59241414; called by muse, mutect2, varscan2
- FCRL2 | c.465C>T p.G155= | Silent (SNP) | VAF 214/369 reads (58%) | catalogued as COSV63832406; called by muse, mutect2, varscan2
- FOXL2NB | c.339C>T p.L113= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs761612537, COSV57725343; called by muse, mutect2, varscan2
- KDM1B | c.2172C>A p.T724= (on ENST00000449850; = p.T491= on NM_153042.4) | Silent (SNP) | VAF 28/127 reads (22%) | catalogued as rs757456976, COSV52808090; called by muse, mutect2, varscan2
- LPA | c.4233T>G p.S1411= | Silent (SNP) | VAF 63/198 reads (32%) | catalogued as COSV60295802, COSV60300847; called by muse, mutect2, varscan2
- NAPEPLD | c.1080G>A p.K360= | Silent (SNP) | VAF 151/535 reads (28%) | catalogued as COSV58521001; called by muse, mutect2, varscan2
- NTNG1 | c.1035C>T p.P345= | Silent (SNP) | VAF 51/117 reads (44%) | catalogued as rs1215823960, COSV53961531; called by muse, mutect2, varscan2
- OR2T4 | c.1011A>G p.L337= | Silent (SNP) | VAF 217/660 reads (33%) | catalogued as COSV63543206; called by muse, mutect2, varscan2
- OR52H1 | c.207C>A p.A69= (on ENST00000322653; = p.A75= on NM_001005289.1) | Silent (SNP) | VAF 78/208 reads (38%) | catalogued as COSV59504741; called by muse, mutect2
- PMEPA1 | c.756G>T p.P252= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs760638901, COSV55691485; called by muse, mutect2, varscan2
- PTPRR | c.810C>T p.H270= | Silent (SNP) | VAF 259/647 reads (40%) | catalogued as rs769263760, COSV51723233; called by muse, mutect2, varscan2
- RABIF | c.102G>C p.G34= | Silent (SNP) | VAF 45/101 reads (45%) | catalogued as COSV66126910; called by muse, mutect2, varscan2
- SCN10A | c.201T>C p.Y67= | Silent (SNP) | VAF 132/305 reads (43%) | catalogued as COSV71860091; called by muse, mutect2, varscan2
- SDK2 | c.4473G>A p.S1491= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs769504258, COSV66180591; called by muse, mutect2, varscan2
- SLC1A7 | c.1281C>G p.L427= | Silent (SNP) | VAF 68/154 reads (44%) | catalogued as COSV57010418, COSV57015034; called by muse, mutect2, varscan2
- SPATC1 | c.1701C>T p.L567= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs140647326, COSV66297995; called by muse, mutect2, varscan2
- SPOCK1 | c.1287T>C p.D429= | Silent (SNP) | VAF 124/287 reads (43%) | catalogued as COSV56435376; called by muse, mutect2, varscan2
- XAB2 | c.1392C>T p.A464= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV50330630; called by muse, mutect2, varscan2
- ZNF436 | c.222A>G p.Q74= | Silent (SNP) | VAF 117/266 reads (44%) | catalogued as rs745363552, COSV58357916; called by muse, mutect2, varscan2
- MIR519D | n.29C>T | RNA (SNP) | VAF 83/220 reads (38%) | catalogued as rs550303151; called by muse, mutect2, varscan2
- TAF10 | c.*310C>T | 3'UTR (SNP) | VAF 24/64 reads (38%) | catalogued as COSV100196364; called by muse, mutect2, varscan2
